Somatic mutation profile of tumor specimen TCGA-BG-A0W1-01A (aliquot TCGA-BG-A0W1-01A-12D-A10G-09) from TCGA case TCGA-BG-A0W1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-BG-A0W1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00ad9f77-f2b4-446e-b497-1c0a8b9d01c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0W1-10A (Blood Derived Normal), aliquot TCGA-BG-A0W1-10A-01D-A117-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d278978-7d9d-480f-8565-7b045d388ca9

The open-access MAF lists 77 somatic variants for this specimen: 58 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, Frame Shift Del 8, In Frame Del 4, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 91/151 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.546C>G p.S182R | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53788393; called by muse, mutect2, varscan2
- AFMID | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59975506; called by muse, mutect2, varscan2
- ALPK3 | c.4313C>T p.S1438L | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775335205, COSV51930604; called by muse, mutect2, varscan2
- APOLD1 | c.671C>T p.A224V (on ENST00000326765 / NM_001130415.2; = p.A193V on NM_030817.3) | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV58732058; called by muse, mutect2, varscan2
- ARID2 | c.4535_4545del p.C1512* | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | catalogued as COSV57597431; called by mutect2, pindel, varscan2
- C16orf70 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); catalogued as rs748098061, COSV54626124; called by muse, mutect2, varscan2
- C1orf116 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.051); catalogued as rs966680282, COSV63943802; called by muse, mutect2, varscan2
- CACNB4 | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 75/131 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); catalogued as rs375245807; called by muse, mutect2, varscan2
- CDH4 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs149315148; called by muse, mutect2, varscan2
- CSMD2 | c.1574G>A p.G525D | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV53885732; called by muse, mutect2, varscan2
- CTNNA3 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 43/101 reads (43%) | catalogued as rs202196166, COSV65522010, COSV65522795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCT | c.428G>C p.G143A | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV65467736; called by muse, mutect2, varscan2
- DNAH17 | c.8521G>A p.A2841T | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs377673048; called by muse, mutect2, varscan2
- DSCAM | c.3206G>T p.R1069L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV68022029; called by muse, mutect2, varscan2
- DVL2 | c.2185A>T p.S729C | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as COSV50034803; called by muse, mutect2, varscan2
- ECPAS | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.067); catalogued as rs1431940775, COSV52192768; called by muse, mutect2, varscan2
- EFTUD2 | c.1544C>T p.T515I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV68182414; called by muse, mutect2, varscan2
- ELFN2 | c.2114G>A p.C705Y | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV68743948; called by muse, mutect2, varscan2
- FLNB | c.1962_1963insA p.L655Ifs*19 | Frame Shift Ins (INS) | VAF 40/141 reads (28%) | catalogued as COSV55872601; called by mutect2, pindel, varscan2
- GALNT8 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs151313517; called by muse, mutect2
- IFT81 | c.1096A>G p.K366E | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as COSV54360984; called by muse, mutect2, varscan2
- IRS4 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as COSV64532840; called by muse, mutect2
- MAP1A | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs986114944, COSV55806664; called by muse, mutect2, varscan2
- NRROS | c.2003C>G p.T668S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as COSV60744808; called by mutect2, varscan2
- OR2M3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 107/433 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV101513423, COSV71758901; called by muse, mutect2, varscan2
- PAK6 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1303293188, COSV53044572; called by muse, mutect2, varscan2
- PLCH1 | c.653del p.Y218Ffs*5 (on ENST00000340059 / NM_001130960.2; = p.Y230Ffs*5 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 108/238 reads (45%) | catalogued as COSV58189099; called by mutect2, pindel, varscan2
- PLEKHA5 | c.995_1002del p.D332Gfs*2 | Frame Shift Del (DEL) | VAF 43/158 reads (27%) | catalogued as COSV54695429; called by mutect2, pindel, varscan2
- POLE2 | c.1044_1048del p.I348Mfs*2 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs749499721; called by mutect2, pindel, varscan2
- PTEN | c.808_812del p.M270Sfs*26 | Frame Shift Del (DEL) | VAF 34/46 reads (74%) | catalogued as COSV64291304; called by pindel, varscan2
- PTGFRN | c.2005C>T p.R669* | Nonsense Mutation (SNP) | VAF 27/44 reads (61%) | catalogued as rs1319107425, COSV67797920; called by muse, mutect2, varscan2
- SAR1A | c.548G>C p.R183T | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV64699472; called by muse, mutect2, varscan2
- SLC16A2 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs201194222, COSV52082951; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC24A3 | c.1781T>G p.V594G | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV60113425; called by muse, mutect2, varscan2
- SLC25A46 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.846); catalogued as COSV63506531; called by muse, mutect2, varscan2
- SNTG1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.19); catalogued as rs201460045, COSV52428603, COSV99386657; called by muse, mutect2, varscan2
- SRP72 | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV61377031; called by muse, mutect2, varscan2
- SYCP2 | c.901C>G p.L301V | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62766424; called by muse, mutect2, varscan2
- TBX22 | c.1028G>A p.C343Y | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64785136, COSV64785254; called by muse, mutect2, varscan2
- TSPAN12 | c.403A>G p.M135V | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV56078736; called by muse, mutect2, varscan2
- TWF1 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57300042; called by muse, mutect2, varscan2
- U2SURP | c.2047G>T p.E683* | Nonsense Mutation (SNP) | VAF 18/168 reads (11%) | catalogued as COSV67530193; called by muse, mutect2, varscan2
- UACA | c.2953T>G p.Y985D | Missense Mutation (SNP) | VAF 148/342 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59853784; called by muse, mutect2, varscan2
- UBQLN2 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV57739117; called by muse, mutect2, varscan2
- USP53 | c.486G>A p.Q162= | Splice Region (SNP) | VAF 69/179 reads (39%) | catalogued as rs774040047, COSV56792763, COSV99917844; called by muse, mutect2
- USP9X | c.628C>G p.R210G | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV61066650; called by muse, mutect2, varscan2
- ZNF518B | c.2924T>C p.L975S | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58721581; called by muse, mutect2, varscan2
- ZZZ3 | c.2082+2T>G p.X694_splice | Splice Site (SNP) | VAF 124/265 reads (47%) | catalogued as COSV66231440; called by muse, mutect2, varscan2
- ASXL1 | c.1877_1886del p.G626Vfs*74 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- ATP6V0A1 | c.381_387del p.E127Dfs*38 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- IFT80 | c.958-7_963del p.X320_splice | Splice Site (DEL) | VAF 55/111 reads (50%) | called by mutect2, pindel, varscan2
- INPPL1 | c.1323del p.N441Kfs*2 | Frame Shift Del (DEL) | VAF 62/171 reads (36%) | called by mutect2, pindel, varscan2
- LILRB2 | c.476_478del p.G159del | In Frame Del (DEL) | VAF 66/175 reads (38%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.2141dup p.G715Rfs*21 | Frame Shift Ins (INS) | VAF 80/223 reads (36%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1744_1745+1del | In Frame Del (DEL) | VAF 71/181 reads (39%) | called by mutect2, pindel, varscan2
- TMED2 | c.550_555del p.T184_L185del | In Frame Del (DEL) | VAF 70/241 reads (29%) | called by mutect2, pindel, varscan2
- TRIM59 | c.862_864del p.E288del | In Frame Del (DEL) | VAF 49/199 reads (25%) | called by pindel, varscan2
- ADAMTSL3 | c.2088G>A p.Q696= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as COSV54438481; called by muse, mutect2, varscan2
- ANO10 | c.1854G>A p.R618= | Silent (SNP) | VAF 57/172 reads (33%) | catalogued as COSV52728946; called by muse, mutect2, varscan2
- ASPHD2 | c.645G>A p.P215= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs754364586, COSV53218268; called by muse, mutect2, varscan2
- CMTM5 | c.487C>T p.L163= (on ENST00000339180 / NM_001288746.2; = p.L96= on NM_138460.3) | Silent (SNP) | VAF 82/157 reads (52%) | catalogued as COSV59304989, COSV59305270; called by muse, mutect2, varscan2
- DNMT1 | c.2787C>T p.N929= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs539948794, COSV61576981; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ERBIN | c.660T>G p.T220= | Silent (SNP) | VAF 78/208 reads (38%) | catalogued as COSV52311792; called by muse, mutect2, varscan2
- IGHG4 | c.438G>A p.V146= | Silent (SNP) | VAF 50/132 reads (38%) | called by muse, mutect2, varscan2
- IGSF10 | c.1695G>A p.R565= | Silent (SNP) | VAF 62/98 reads (63%) | catalogued as rs758154653, COSV56782287; called by muse, mutect2
- ITCH | c.1650T>A p.I550= (on ENST00000262650 / NM_001257137.3; = p.I509= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/276 reads (4%) | catalogued as COSV52929878; called by muse, mutect2
- JARID2 | c.1158C>G p.T386= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV59186228; called by muse, mutect2
- MAP1S | c.2319G>A p.R773= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV60721911; called by mutect2, varscan2
- MAPK9 | c.1086T>C p.D362= | Silent (SNP) | VAF 143/336 reads (43%) | catalogued as COSV58119252; called by muse, mutect2, varscan2
- MTA1 | c.33C>T p.Y11= | Silent (SNP) | VAF 46/84 reads (55%) | catalogued as rs148162904; called by muse, mutect2, varscan2
- MYH13 | c.1845G>A p.S615= | Silent (SNP) | VAF 75/173 reads (43%) | catalogued as rs778246169, COSV52822114, COSV52842878; called by muse, mutect2, varscan2
- MYH8 | c.1908G>A p.A636= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs759093798, COSV67960897; called by muse, mutect2, varscan2
- PRRC2C | c.5046T>C p.G1682= (on ENST00000367742; = p.G1680= on NM_015172.4) | Silent (SNP) | VAF 32/370 reads (9%) | catalogued as COSV58901987; called by muse, mutect2
- SLCO5A1 | c.567C>T p.G189= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1428621171, COSV52654930; called by muse, mutect2
- TIE1 | c.1173C>T p.D391= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs759805607, COSV65248766; called by muse, mutect2, varscan2
- Y_RNA | chr14:50083764 G>A | 5'Flank (SNP) | VAF 16/36 reads (44%) | catalogued as rs866044951; called by muse, mutect2, varscan2
